Surgical pathology report (de-identified scan), TCGA case TCGA-G2-AA3F, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site MD Anderson, specimen TCGA-G2-AA3F-01A (Primary Tumor).

ICD-O-3
Carcinoma, urothelial NOS
8/20/13
Site Bladder NOS
C67.9
9/20/17/14

DIAGNOSIS

(A) BLADDER TUMOR:

UROTHELIAL CARCINOMA, HIGH GRADE (GRADE 3) WITH MICROPAPILLARY FEATURES (15%), INVASIVE INTO MUSCULARIS PROPRIA..

LYMPHOVASCULAR INVASION PRESENT.

Prostatic tissue with stromal nodular hyperplasia, negative for adenocarcinoma.

GROSS DESCRIPTION

(A) BLADDER TUMOR - Multiple light gray and dark brown unoriented fragments of soft tissue (8.0 x 7.5 x 4.5 cm in aggregate).

SECTION CODE: A1-A10, representative fragments are submitted.

CLINICAL HISTORY

Bladder cancer.

CLINICAL HISTORY

Bladder cancer.

Source: NCI Genomic Data Commons file d686d7b8-216f-4ac4-a526-d2ab93c11b46 (TCGA-G2-AA3F.3421B447-B005-4F3D-9FAD-50C980F90F06.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).